TCGA case TCGA-97-8176 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12c27db5-db2f-48dc-a2ca-9557b951f43e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 468 days (1.3 years).

Diagnoses (2)
1. Acinar cell carcinoma (the primary disease): ICD-O-3 morphology code: 8550/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 63.4 years (23,170 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 51 days; Days to treatment end: 64 days; Treatment dose: 3,000 cGy; Treatment outcome: Partial Response; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 77 days; Days to treatment end: 161 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Cyanocobalamin; Days to treatment start: 77 days; Days to treatment end: 417 days (1.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Denosumab + Pegfilgrastim; Days to treatment start: 77 days; Days to treatment end: 417 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Days to treatment start: 77 days; Days to treatment end: 417 days (1.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 91 days; Days to treatment end: 105 days; Treatment dose: 3,000 cGy; Treatment outcome: Partial Response; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 91 days; Days to treatment end: 105 days; Treatment dose: 1,500 cGy; Treatment outcome: Partial Response; Number of fractions: 5; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Acinar cell carcinoma). Age at diagnosis: 63.5 years (23,209 days); Days to diagnosis: 39 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 171 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 39 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 39 days; Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 252 days; Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 468.

Molecular and laboratory tests
- KRAS substitution: Positive; Amino-acid change: G12S.

Other clinical attributes
- DLCO (% of predicted): 61; FEV1/FVC after bronchodilator (%): 68; FEV1/FVC before bronchodilator (%): 67; FEV1 after bronchodilator (% of reference): 104; FEV1 before bronchodilator (% of reference): 100.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1971; Tobacco smoking quit year: 2011.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-8176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.1; Intermediate dimension: 2; Shortest dimension: 0.3.
  Slide TCGA-97-8176-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-97-8176-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Acinar Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; KRAS mutation found: Yes; KRAS gene analysis indicator: Yes; KRAS mutation identified type: G12S; EGFR mutation status: Yes; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.
- Drug treatment 3: Pharmaceutical therapy drug name: B12.
- Drug treatment 4: Pharmaceutical therapy drug name: Neulasta.
- Drug treatment 5: Pharmaceutical therapy drug name: Xgeva.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 468 days; disease-specific survival: no event (censored), 468 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 39 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-8176-01A-11D-2389-01): tumor purity 0.53, ploidy 1.91, whole-genome doublings 0.
